Gene-level copy-number profile of tumor specimen TCGA-CJ-4901-01A from TCGA case TCGA-CJ-4901, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 47.6 years (17,396 days).
Specimen TCGA-CJ-4901-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.cfae5bb2-a73d-4eae-bee9-e042b3e8c82d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CJ-4901-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2953a849-171e-47fe-843c-55f62307a681

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,383; copy number 2: 23,931; copy number 3: 5,329; copy number 4: 20,688; copy number 5: 7,338; copy number 6: 1,151.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CJ-4901-01A-01D-1423-01): tumor purity 0.32, ploidy 2.72, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,489 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:163,743,913–242,160,153, 1,383 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:106,415,576–172,952,683, 1,151 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr7:70,972–159,233,377, 3,014 genes, copy number 5 (broad region; genes not listed).
- chr8:107,857,589–145,066,685, 563 genes, copy number 5 (broad region; genes not listed).
- chr17:51,336,646–83,095,122, 920 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,383. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
